Gene-level copy-number profile of tumor specimen TCGA-J2-A4AE-01A from TCGA case TCGA-J2-A4AE, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.1 years (28,163 days).
Specimen TCGA-J2-A4AE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.c6895bd2-ff7d-4a19-bf92-f44ff1685cbf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-J2-A4AE-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b4989686-03ab-427f-b641-ce81c4a29eee

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,979; copy number 2: 43,568; copy number 3: 7,441; copy number 4: 4,941; copy number 5: 881.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-J2-A4AE-01A-21D-A24C-01): tumor purity 0.52, ploidy 2.18, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 881 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:70,972–15,068,651, 258 genes, copy number 5 (broad region; genes not listed).
- chr7:24,132,705–46,481,578, 455 genes, copy number 5 (broad region; genes not listed).
- chr7:53,366,058–62,275,678, 168 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,979. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
